Gene-level copy-number profile of tumor specimen TCGA-4Z-AA7S-01A from TCGA case TCGA-4Z-AA7S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,111 days).
Specimen TCGA-4Z-AA7S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e14e42a1-3b00-489f-aa16-7453e2a2b329.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA7S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84b59008-9c9c-4f44-9fa0-df366b4efc1f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 2,164; copy number 3: 13,387; copy number 4: 37,095; copy number 5: 3,677; copy number 6: 3,216; copy number 7: 34; copy number 10: 3; copy number 19: 94; copy number 21: 53; copy number 22: 6; copy number 24: 13; copy number 39: 18; copy number 50: 13; copy number 51: 19; copy number 58: 19; copy number 97: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA7S-01A-11D-A390-01): tumor purity 0.87, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,501,109–186,555,567, 2 genes: RNU6-1055P, MTNR1A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 240 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:135,181,308–135,813,990, 13 genes, copy number 24: MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1.
- chr8:99,796,615–100,501,148, 20 genes, copy number 19: AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2.
- chr8:100,685,816–103,298,772, 74 genes, copy number 19 (within-gene range 4–19) (broad region; genes not listed).
- chr11:68,754,620–70,436,584, 52 genes, copy number 21: CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 21: AP001271.1.
- chr12:57,723,761–60,269,686, 49 genes, copy number 39–58 (within-gene range 4–58): AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1.
- chr12:69,212,108–69,738,574, 19 genes, copy number 51 (within-gene range 4–51): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1.
- chr17:18,943,999–18,944,073, 1 gene, copy number 97: AC090286.2.
- chr17:18,951,625–18,954,149, 1 gene, copy number 97: AC090286.1.
- chr17:39,671,122–39,864,312, 6 genes, copy number 22 (within-gene range 3–22): PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:53,353,427–53,682,111, 4 genes, copy number 10–50: AC005341.1, AC090079.1, AC090079.2, AC034268.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
